Somatic mutation profile of tumor specimen TCGA-55-6986-01A (aliquot TCGA-55-6986-01A-11D-1945-08) from TCGA case TCGA-55-6986, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-55-6986-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59921574-8bc1-4fd9-b89c-ba571288ee9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6986-11A (Solid Tissue Normal), aliquot TCGA-55-6986-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5282f995-7763-4acb-aa70-99e1d8f27272

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 12, Silent 6, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACER2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV61821684; called by muse, mutect2, varscan2
- CCDC9B | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs370895955; called by muse, mutect2, varscan2
- DPF2 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs373186765, COSV52890310; called by muse, mutect2, varscan2
- EFEMP2 | c.827T>C p.L276P | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as COSV57261765; called by muse, mutect2, varscan2
- EMILIN2 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV54428411; called by muse, mutect2, varscan2
- FAM83C | c.1825C>A p.P609T | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.11); catalogued as COSV65584823; called by muse, mutect2, varscan2
- HAPLN1 | c.977G>A p.S326N | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV57152654; called by muse, mutect2, varscan2
- KIF11 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53274784; called by muse, mutect2, varscan2
- PSG4 | c.827A>G p.N276S | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV54942017; called by muse, mutect2
- PSG8 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 24/257 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV60613910; called by muse, mutect2
- SRGAP3 | c.2326C>T p.R776C | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1197881650, COSV64535598; called by muse, mutect2, varscan2
- STX12 | c.792C>G p.I264M | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV64250160; called by muse, mutect2, varscan2
- MED23 | c.2335dup p.H779Pfs*26 | Frame Shift Ins (INS) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- SETD2 | c.5619del p.K1874Rfs*3 | Frame Shift Del (DEL) | VAF 10/83 reads (12%) | called by mutect2, pindel, varscan2
- SETD2 | c.4603_4604del p.N1535Wfs*7 | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | called by mutect2, pindel, varscan2
- ALDH6A1 | c.42C>T p.I14= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV63247521; called by muse, mutect2, varscan2
- DAW1 | c.477T>C p.C159= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV59369850; called by muse, mutect2, varscan2
- PNLIPRP1 | c.948G>A p.P316= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs368268520; called by muse, mutect2, varscan2
- PRDM9 | c.2598G>A p.G866= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as rs1225378970, COSV57014623; called by muse, mutect2, varscan2
- SLC22A13 | c.91C>T p.L31= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs1559535494, COSV61292154, COSV61292403; called by muse, mutect2, varscan2
- SSTR2 | c.345C>T p.C115= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV59536228; called by muse, mutect2, varscan2
